Somatic mutation profile of tumor specimen MP2PRT-PAPDEU-TMP1-A (aliquot MP2PRT-PAPDEU-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPDEU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,426 days).
Specimen MP2PRT-PAPDEU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11b17aab-9717-422f-8e4d-e5ef999c0c75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDEU-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDEU-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7427dc3c-2f8c-42eb-aae3-a32ad62bf756

The open-access MAF lists 76 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Nonsense Mutation 7, Frame Shift Ins 2, RNA 1, Intron 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.6853G>A p.G2285R | Missense Mutation (SNP) | VAF 110/599 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268762655, COSV55105527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 114/515 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4439C>T p.S1480L (on ENST00000272895 / NM_173076.3; = p.S1162L on NM_015657.3) | Missense Mutation (SNP) | VAF 23/597 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs888992711; called by muse, mutect2
- ADAMTS5 | c.2734G>T p.G912* | Nonsense Mutation (SNP) | VAF 229/794 reads (29%) | catalogued as COSV53178471; called by muse, mutect2, varscan2
- BSN | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 46/720 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1336122554; called by muse, mutect2
- CLVS2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 168/752 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.398); catalogued as COSV51560331; called by muse, mutect2, varscan2
- CSMD3 | c.5124G>A p.M1708I (on ENST00000297405 / NM_001363185.1; = p.M1604I on NM_052900.3) | Missense Mutation (SNP) | VAF 183/477 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs866818702, COSV52100363; called by muse, mutect2, varscan2
- FAT2 | c.13036G>A p.E4346K | Missense Mutation (SNP) | VAF 222/501 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1368203978; called by muse, mutect2, varscan2
- GCN1 | c.3711G>T p.L1237F | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1397020113; called by muse, mutect2
- GPAT2 | c.1045dup p.L349Pfs*13 | Frame Shift Ins (INS) | VAF 122/549 reads (22%) | catalogued as rs1254245136; called by mutect2, varscan2
- GRM8 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 136/644 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); catalogued as rs142400397, COSV58834505; called by muse, mutect2, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 218/464 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2, varscan2
- KIAA1210 | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 437/979 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV68179065; called by muse, mutect2, varscan2
- KIR2DS4 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 144/159 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs774017829; called by muse, mutect2, varscan2
- LRRCC1 | c.1958G>C p.R653T | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835546; called by muse, mutect2
- MROH2B | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.464); catalogued as rs866010781, COSV68181253, COSV68189614; called by muse, mutect2, varscan2
- MXRA5 | c.5653G>A p.V1885I | Missense Mutation (SNP) | VAF 120/467 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765680927, COSV99476989; called by muse, mutect2, varscan2
- PKLR | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 48/742 reads (6%) | catalogued as rs971962553, COSV61360923; called by muse, mutect2
- PLEKHB2 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV58239080; called by muse, mutect2
- RYR2 | c.14369G>A p.R4790Q | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750780758, CM097942, COSV63675870; called by muse, mutect2, varscan2
- SHANK2 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 196/757 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1244880154; called by muse, mutect2, varscan2
- SUPT6H | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 183/485 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58930768; called by muse, mutect2, varscan2
- SYT6 | c.962G>A p.R321H (on ENST00000610222 / NM_001366225.1; = p.R236H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/621 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs549305784, COSV65773471, COSV65774250; called by muse, mutect2, varscan2
- THADA | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 22/563 reads (4%) | catalogued as COSV67089725; called by muse, mutect2
- TMEM131L | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV68800161; called by muse, mutect2, varscan2
- TRPC4 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 248/537 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV58995967, COSV59015048; called by muse, mutect2, varscan2
- VSIG2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 37/655 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs560857446, COSV99423167; called by muse, mutect2
- ZNF334 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 242/574 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61618072; called by muse, mutect2, varscan2
- ABCA1 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 36/680 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ADAM7 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 65/405 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALG13 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRWD3 | c.5137G>T p.G1713* | Nonsense Mutation (SNP) | VAF 394/902 reads (44%) | called by muse, mutect2, varscan2
- BTBD8 | c.4648C>T p.L1550F (on ENST00000636805 / NM_001376131.1; = p.L1037F on NM_015237.4) | Missense Mutation (SNP) | VAF 269/598 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- C6orf118 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CAND1 | c.492G>T p.R164S | Missense Mutation (SNP) | VAF 178/398 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DIAPH2 | c.2455C>G p.L819V | Missense Mutation (SNP) | VAF 70/712 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DOCK5 | c.4523C>T p.S1508L | Missense Mutation (SNP) | VAF 173/443 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- DRP2 | c.271C>G p.H91D | Missense Mutation (SNP) | VAF 21/630 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2
- FAM205A | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 212/466 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- FAM83C | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 275/748 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMR1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 289/685 reads (42%) | called by muse, mutect2, varscan2
- FSIP2 | c.3937C>T p.H1313Y | Missense Mutation (SNP) | VAF 146/330 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2 | c.2920T>C p.F974L | Missense Mutation (SNP) | VAF 183/696 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- HOXA4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 247/515 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-45 | c.353delinsTCGC | In Frame Ins (INS) | VAF 126/296 reads (43%) | called by mutect2*, pindel, varscan2*
- IGHV3-43 | chr14:106470261 del TGTAT | Missense Mutation (DEL) | VAF 110/123 reads (89%) | called by mutect2, pindel*, varscan2
- JAKMIP3 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 84/878 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- MON2 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 36/586 reads (6%) | called by muse, mutect2
- NSDHL | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 198/515 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13D1 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR13J1 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 105/602 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAWR | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 18/660 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHB2 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 161/637 reads (25%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLA2G4A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 188/481 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTBP2 | c.1253C>G p.S418C (on ENST00000426398 / NM_001300986.2; = p.S410C on NM_021190.4) | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ROR1 | c.1790T>C p.I597T | Missense Mutation (SNP) | VAF 155/616 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SH2B3 | c.630_631insTC p.M211Sfs*68 | Frame Shift Ins (INS) | VAF 327/894 reads (37%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 168/382 reads (44%) | called by muse, mutect2, varscan2
- USP6 | c.2432-1G>A p.X811_splice | Splice Site (SNP) | VAF 124/271 reads (46%) | called by muse, mutect2, varscan2
- ANKRD20A4P | c.2454T>A p.T818= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- CCDC168 | c.11037C>T p.I3679= | Silent (SNP) | VAF 28/625 reads (4%) | catalogued as rs762572216; called by muse, mutect2
- COL20A1 | c.516C>T p.C172= | Silent (SNP) | VAF 270/651 reads (41%) | catalogued as rs779217673; called by muse, mutect2, varscan2
- CYP4A11 | c.645G>A p.Q215= | Silent (SNP) | VAF 148/321 reads (46%) | called by muse, mutect2, varscan2
- GLI3 | c.3046C>T p.L1016= | Silent (SNP) | VAF 448/1051 reads (43%) | called by muse, mutect2
- HS1BP3 | c.1122C>T p.I374= | Silent (SNP) | VAF 250/684 reads (37%) | called by muse, mutect2
- ISLR | c.1209G>A p.G403= | Silent (SNP) | VAF 396/477 reads (83%) | called by muse, mutect2, varscan2
- LRIT1 | c.924G>A p.T308= | Silent (SNP) | VAF 270/571 reads (47%) | catalogued as rs775567982, COSV100927965; called by muse, mutect2, varscan2
- LRRIQ3 | c.474G>C p.V158= | Silent (SNP) | VAF 33/528 reads (6%) | called by muse, mutect2
- NRXN2 | c.2649T>C p.S883= | Silent (SNP) | VAF 168/843 reads (20%) | called by muse, mutect2, varscan2
- PDE1C | c.1269T>A p.V423= | Silent (SNP) | VAF 206/495 reads (42%) | catalogued as COSV100371501; called by muse, mutect2, varscan2
- POTEF | c.1650C>T p.V550= | Silent (SNP) | VAF 236/278 reads (85%) | catalogued as rs1349264633, COSV100664662, COSV100665212; called by muse, mutect2, varscan2
- SLITRK2 | c.753G>A p.G251= | Silent (SNP) | VAF 403/849 reads (47%) | called by muse, mutect2, varscan2
- TMEM131 | c.300C>G p.L100= | Silent (SNP) | VAF 26/598 reads (4%) | called by muse, mutect2
- VWA5B1 | c.2565G>T p.A855= | Silent (SNP) | VAF 408/851 reads (48%) | catalogued as rs1024775309; called by muse, mutect2, varscan2
- DCHS2 | n.5745C>T | RNA (SNP) | VAF 200/485 reads (41%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+13929C>T | Intron (SNP) | VAF 207/470 reads (44%) | called by muse, mutect2, varscan2
